Somatic mutation profile of tumor specimen 0DR7Y8 from CCDI case PBCGEE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (750 days).
Specimen 0DR7Y8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a37b2ec-3c0f-4eef-8b97-f19b8708446a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR7YF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9e61684-9309-4d6c-9b91-695b4520f7df

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.4024G>T p.G1342* (on ENST00000303395 / NM_001202435.3; = p.G1331* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 658/1678 reads (39%) | catalogued as rs1553525358; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP170B | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 269/633 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388237107; called by muse, mutect2, varscan2
- PDCD2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 334/816 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs749670057; called by muse, mutect2, varscan2
